TCGA case TCGA-CM-4748 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cd845618-4cc4-49c2-9055-c171d4c24ee1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.4; Tissue or organ of origin: Transverse colon; Site of resection or biopsy: Transverse colon; Classification of tumor: primary; Age at diagnosis: 53.4 years (19,509 days); Year of diagnosis: 2010; AJCC pathologic T: T4a; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0; Days to last follow up: 792 days (2.2 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 23; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 229 days; Number of cycles: 12; Treatment dose: 10,200 mg; Prescribed dose: 850; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 229 days; Number of cycles: 12; Treatment dose: 30,011 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 229 days; Number of cycles: 12; Treatment dose: 10,200 mg; Prescribed dose: 850; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 229 days; Number of cycles: 12; Treatment dose: 185 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 153 days; Days to treatment end: 214 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Days to treatment start: 276 days; Days to treatment end: 365 days (1.0 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Days to treatment start: 304 days; Days to treatment end: 335 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Floxuridine; Days to treatment start: 396 days (1.1 years); Days to treatment end: 518 days (1.4 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin Calcium; Days to treatment start: 396 days (1.1 years); Days to treatment end: 518 days (1.4 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab + Irinotecan Hydrochloride; Days to treatment start: 670 days (1.8 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 214 days; Disease response: Tumor Free.
- Days to follow up: 792 days (2.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 2 ng/mL.
- MLH1 (IHC): Loss of Expression.
- MSH2 (IHC): Loss of Expression.
- MSH6 (IHC): Loss of Expression.
- PMS2 (IHC): Loss of Expression.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 89.8 kg; Height: 176 cm; BMI: 29.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CM-4748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 1.5; Shortest dimension: 0.3.
  Slide TCGA-CM-4748-01A-01-BS1: Section location: Bottom; Percent tumor cells: 82; Percent tumor nuclei: 75; Percent normal cells: 1; Percent necrosis: 2; Percent stromal cells: 15.
  Slide TCGA-CM-4748-01A-01-TS1: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 15.
- Sample TCGA-CM-4748-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CM-4748-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 2; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Not Expressed; Mismatch rep proteins loss IHC: MSH2-Not Expressed; Mismatch rep proteins loss IHC: PMS2-Not Expressed; Mismatch rep proteins loss IHC: MSH6-Not Expressed.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 6: Pharmaceutical therapy drug name: IRINOtecan HCl.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 792 days; disease-specific survival: no event (censored), 792 days; disease-free interval: no event (censored), 792 days; progression-free interval: no event (censored), 792 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CM-4748-01A-01D-1406-01): tumor purity 0.63, ploidy 1.99, whole-genome doublings 0.
